Surgical pathology report (de-identified scan), TCGA case TCGA-S9-A6U6, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Dept of Neurosurgery at University of Heidelberg, specimen TCGA-S9-A6U6-01A (Primary Tumor).

Histomorphology demonstrates astrocytic differentiation. Single mitoses detectable.
Proliferation up to 7%. Due to foci of increased cellularity and increased mitotic activity, this tumor is graded III according to WHO.

CMF

ICD-O-3

path Astrocytoma, grade III 9401/3

Astrocytoma, anaplastic 9401/3

Site: Brain, supratentorial NOS C71.0

JW 7/25/13

Diagnosis

Anaplastic astrocytoma WHO grade III

untranslated original report
is housed at the BCR.

Source: NCI Genomic Data Commons file 8c4c1ca3-eb40-4e1d-8327-287d030e5ffa (TCGA-S9-A6U6.741221A4-D7C5-45F8-9D69-8FDD835D019A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).